Somatic mutation profile of tumor specimen TCGA-EE-A2MR-06A (aliquot TCGA-EE-A2MR-06A-11D-A196-08) from TCGA case TCGA-EE-A2MR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.9 years (24,783 days).
Specimen TCGA-EE-A2MR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7149115-6354-4df3-8809-0cccaeafffd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MR-10A (Blood Derived Normal), aliquot TCGA-EE-A2MR-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c5efd8-71a4-49e7-ae0e-a8239f819471

The open-access MAF lists 3,784 somatic variants for this specimen: 2,289 protein-altering or splice-affecting, 1,416 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,102, Silent 1,416, Nonsense Mutation 123, Intron 34, Splice Site 32, RNA 29, Splice Region 23, Frame Shift Del 5, 3'UTR 5, 5'Flank 5, 5'UTR 3, Translation Start Site 3.

Variants (750 of 3,784; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL6 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs867576130, COSV51651017; called by muse, mutect2, varscan2
- DYSF | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150877497, CM033374; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- GCK | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.994); catalogued as rs1554335570, CM012114, COSV60786442; ClinVar: likely pathogenic; called by muse, mutect2
- GDF5 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121909350, CM085446, COSV65500464; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569017114, COSV65567150; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTRR | c.1442C>T p.S481L (on ENST00000264668; = p.S454L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853062, CM032288, COSV52942686; ClinVar: pathogenic; called by mutect2, varscan2
- NPC1 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298238512, CD149613, CM032620, COSV52577772; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PCED1B | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 28/182 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs757280610, COSV71394886, COSV71395186; called by muse, mutect2, varscan2
- RPGRIP1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs192003551, CM130723, COSV52847714; ClinVar: pathogenic; called by mutect2, varscan2
- SDR9C7 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs538068583, COSV53288872; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABCA13 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV70027206; called by mutect2, varscan2
- ABCA3 | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.544); catalogued as COSV100068022; called by muse, mutect2, varscan2
- ABCA3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs148726153; called by mutect2, varscan2
- ABCA4 | c.4187C>T p.P1396L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64672608; called by muse, mutect2, varscan2
- ABCB1 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV55948528; called by muse, mutect2, varscan2
- ABCB11 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55588275; called by muse, mutect2, varscan2
- ABCB5 | c.1838G>A p.R613Q (on ENST00000404938 / NM_001163941.2; = p.R168Q on NM_178559.6) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1187222290, COSV51706928; called by muse, mutect2, varscan2
- ABCC11 | c.3472C>T p.L1158F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62322292; called by muse, mutect2, varscan2
- ABCC12 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912507; called by muse, mutect2, varscan2
- ABCC4 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.33); catalogued as COSV65311201; called by muse, mutect2, varscan2
- ABCC8 | c.3926G>A p.G1309E | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1564878341, COSV56848501; called by muse, varscan2
- ABCC8 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs1395033115, COSV56847793; called by muse, varscan2
- ABCC9 | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53967147, COSV99686027; called by muse, mutect2, varscan2
- ABCC9 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53967170; called by muse, mutect2, varscan2
- ABCC9 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772070154, COSV99684538; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCG2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1423601232, COSV52944808, COSV52944909; called by muse, mutect2, varscan2
- ABCG5 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV53210176; called by muse, mutect2
- ABCG8 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 82/228 reads (36%) | catalogued as COSV55391996; called by muse, varscan2
- ABCG8 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs776775584, COSV55391415; called by muse, varscan2
- ABL2 | c.611C>T p.P204L (on ENST00000502732 / NM_007314.4; = p.P189L on NM_005158.5) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1409618809, COSV100772450; called by muse, varscan2
- ABL2 | c.610C>T p.P204S (on ENST00000502732 / NM_007314.4; = p.P189S on NM_005158.5) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100772456; called by muse, varscan2
- AC004922.1 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV53163036; called by muse, mutect2, varscan2
- AC006059.2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV59606417; called by muse, mutect2
- AC008397.2 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV53206204; called by muse, varscan2
- AC008397.2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs746162922, COSV53206219, COSV53208687; called by muse, mutect2, varscan2
- AC100868.1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.236); catalogued as COSV51840631; called by muse, mutect2
- ACAD10 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58155518; called by muse, mutect2, varscan2
- ACAN | c.1673A>T p.Y558F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61358699; called by mutect2, varscan2
- ACBD5 | c.1051C>T p.R351C (on ENST00000375888 / NM_001352568.1; = p.R342C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755306488, COSV65517960; called by muse, mutect2, varscan2
- ACCS | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs758423933, COSV55457716; called by mutect2, varscan2
- ACE | c.2913-1G>A p.X971_splice | Splice Site (SNP) | VAF 13/111 reads (12%) | catalogued as COSV52005409; called by muse, mutect2, varscan2
- ACE2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV53024444; called by muse, mutect2, varscan2
- ACHE | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399916623, COSV53816542; called by muse, mutect2, varscan2
- ACOT11 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776181783, COSV56363572; called by muse, mutect2, varscan2
- ACOXL | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1381327868, COSV61323492; called by muse, mutect2, varscan2
- ACR | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV53360752; called by muse, mutect2, varscan2
- ACRV1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1331576080, COSV59754748; called by muse, mutect2
- ACRV1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV59754755, COSV59755104; called by muse, mutect2
- ACSBG1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs1301475681, COSV51904816; called by muse, mutect2, varscan2
- ACSBG2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53123844; called by mutect2, varscan2
- ACSM5 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59370543, COSV59374604; called by muse, mutect2
- ACSS2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53624061; called by muse, mutect2, varscan2
- ACSS3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV54088412; called by muse, varscan2
- ACTBL2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV70661161; called by muse, mutect2
- ACTG1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59510056; called by muse, mutect2, varscan2
- ACTN3 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV59748178; called by muse, mutect2, varscan2
- ADAD1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56642550, COSV99635398; called by muse, varscan2
- ADAM18 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV55845808; called by muse, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by mutect2, varscan2
- ADAM28 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56098122; called by muse, mutect2, varscan2
- ADAM29 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63662370; called by mutect2, varscan2
- ADAM30 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 158/791 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65560749; called by muse, mutect2, varscan2
- ADAM7 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51537821, COSV51546204; called by muse, varscan2
- ADAMTS14 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763213695, COSV64599858; called by mutect2, varscan2
- ADAMTS16 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760889068, COSV56984347; called by muse, mutect2, varscan2
- ADAMTS4 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV63489678; called by muse, mutect2, varscan2
- ADAMTSL2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746426923, COSV63203761; called by muse, mutect2, varscan2
- ADAMTSL5 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867723525, COSV100389063; called by muse, mutect2, varscan2
- ADAP2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58295590; called by muse, mutect2, varscan2
- ADARB1 | c.1594C>T p.P532S (on ENST00000360697 / NM_001346687.2; = p.P492S on NM_001112.4) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62343105; called by muse, mutect2, varscan2
- ADCY1 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV52032682; called by muse, mutect2, varscan2
- ADCY1 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52032703; called by muse, mutect2
- ADCY10 | c.4328C>T p.S1443F | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63239702; called by muse, mutect2, varscan2
- ADCY5 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs148824947; called by muse, varscan2
- ADCY9 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV53573848; called by muse, mutect2
- ADD2 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs868915520, COSV100035178, COSV52458363; called by muse, mutect2, varscan2
- ADGRB2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57072400; called by muse, varscan2
- ADGRE1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs542090314, COSV51674193; called by mutect2, varscan2
- ADGRE1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV51674201; called by muse, mutect2, varscan2
- ADGRE1 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51672821, COSV51674243; called by muse, mutect2, varscan2
- ADGRF1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV64799841; called by muse, mutect2, varscan2
- ADGRG4 | c.7835C>T p.S2612L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54961470; called by mutect2, varscan2
- ADGRL2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661848; called by muse, mutect2, varscan2
- ADGRL4 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV66060891; called by muse, mutect2, varscan2
- ADGRV1 | c.14800G>A p.E4934K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.366); catalogued as COSV67982313; called by muse, mutect2, varscan2
- ADGRV1 | c.16587G>A p.M5529I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV67982707; called by muse, mutect2, varscan2
- ADH1A | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV52924638; called by muse, mutect2, varscan2
- ADH1C | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV72463424; called by mutect2, varscan2
- ADRA1A | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV52360886, COSV52363717; called by muse, mutect2
- AFDN | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 23/147 reads (16%) | catalogued as rs778113186, COSV60038899; called by muse, mutect2, varscan2
- AFM | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56919640; called by muse, mutect2, varscan2
- AGAP2 | c.2716G>A p.E906K (on ENST00000547588 / NM_001122772.2; = p.E550K on NM_014770.4) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV57727506; called by muse, mutect2
- AGAP6 | c.1591C>T p.P531S (on ENST00000374056 / NM_001365867.1; = p.P554S on NM_001077665.2) | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65017540; called by muse, mutect2, varscan2
- AGFG1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV59511242; called by muse, mutect2, varscan2
- AGL | c.3523C>T p.L1175F | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54050974; called by muse, mutect2
- AGO4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751046556, COSV64616822; called by muse, mutect2, varscan2
- AGR3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs746862695, COSV60037702; called by mutect2, varscan2
- AGRN | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1037530738, COSV65068827; called by muse, mutect2, varscan2
- AHCY | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV54152945; called by muse, mutect2, varscan2
- AHNAK2 | c.13007C>T p.S4336F | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs761847400, COSV60912255; called by muse, mutect2, varscan2
- AHNAK2 | c.8287C>T p.P2763S | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.209); catalogued as COSV60912267; called by muse, mutect2, varscan2
- AIM2 | c.267T>A p.D89E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV63699171; called by muse, mutect2
- AJAP1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450188; called by muse, mutect2, varscan2
- AK7 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as rs777849703, COSV50869905; called by mutect2, varscan2
- AK7 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs1212859548, COSV50870441; called by muse, varscan2
- AKAP1 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV58469492; called by muse, mutect2
- AKAP13 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100773161; called by mutect2, varscan2
- AKAP13 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV63453053; called by mutect2, varscan2
- AKT2 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60908088, COSV60908557; called by muse, mutect2, varscan2
- AL121899.2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67350026; called by muse, mutect2, varscan2
- AL121899.2 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67349674, COSV67350073; called by muse, mutect2, varscan2
- AL645922.1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.083); catalogued as COSV100191166, COSV54960036; called by muse, mutect2
- AL645922.1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747684994, COSV100190652; called by muse, mutect2
- ALDH1L1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV56412643; called by muse, mutect2, varscan2
- ALDH4A1 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444617914, COSV51891410; called by muse, mutect2, varscan2
- ALDH7A1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs181287032, COSV63160706; ClinVar: uncertain significance; called by mutect2, varscan2
- ALDH9A1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770756608, COSV61339590; called by mutect2, varscan2
- ALKBH1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs763045994, COSV53659361; called by mutect2, varscan2
- ALMS1 | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV52507131; called by muse, mutect2, varscan2
- ALMS1 | c.6415C>T p.P2139S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as rs772858451, COSV52507141; called by muse, mutect2, varscan2
- ALOX5 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100979962; called by muse, mutect2, varscan2
- ALOXE3 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59074959; called by muse, mutect2, varscan2
- ALPG | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs752707792, COSV54965633; called by mutect2, varscan2
- ALPP | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67396129; called by muse, mutect2, varscan2
- AMBRA1 | c.1042C>T p.P348S (on ENST00000458649 / NM_001367468.1; = p.P258S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV54051594; called by muse, mutect2, varscan2
- AMPD1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV62415644; called by muse, mutect2
- AMPH | c.1881G>A p.V627= | Splice Region (SNP) | VAF 9/98 reads (9%) | catalogued as rs1476193041, COSV57738678; called by muse, mutect2
- ANK1 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV55878402; called by muse, mutect2
- ANK1 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs375850314, COSV55878412; called by mutect2, varscan2
- ANKRD22 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.075); catalogued as COSV64235879; called by muse, mutect2
- ANKRD24 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV53669209; called by muse, mutect2, varscan2
- ANKRD26 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV65793726; called by muse, mutect2, varscan2
- ANKRD35 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.419); catalogued as COSV62910016; called by muse, varscan2
- ANKRD35 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV62910013; called by muse, varscan2
- ANKS4B | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs1206762535, COSV61139010; called by muse, mutect2, varscan2
- ANLN | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV56075062; called by muse, mutect2, varscan2
- ANO2 | c.1489G>A p.E497K (on ENST00000356134 / NM_001278597.3; = p.E501K on NM_001278596.3) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59015810; called by muse, mutect2, varscan2
- ANO2 | c.382G>A p.G128S (on ENST00000356134 / NM_001278597.3; = p.G132S on NM_001278596.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.138); catalogued as COSV59015844; called by muse, mutect2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by mutect2, varscan2
- ANTXR2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs1320336898, COSV56314169; called by muse, mutect2, varscan2
- AOAH | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51738460; called by muse, mutect2
- AOX1 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV65980051; called by muse, mutect2, varscan2
- AP2B1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV51998355, COSV99251486; called by muse, mutect2
- AP4B1 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200276550, COSV56723272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as COSV55702722, COSV99697497; called by muse, mutect2
- APOB | c.12731C>T p.S4244F | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV51921429; called by muse, mutect2, varscan2
- APOB | c.12317G>A p.R4106K | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.133); catalogued as COSV51930849; called by muse, mutect2, varscan2
- APOB | c.5221G>A p.D1741N | Missense Mutation (SNP) | VAF 39/637 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.113); catalogued as COSV51930889; called by muse, mutect2
- APOBEC3A | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs867336934, COSV50779174; called by muse, mutect2, varscan2
- APOH | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99235554; called by muse, mutect2, varscan2
- APTX | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV58928258; called by muse, mutect2, varscan2
- AQR | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50031629, COSV99334705; called by muse, mutect2
- AR | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65952593, COSV65965052; called by muse, mutect2, varscan2
- ARHGAP21 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.849); catalogued as COSV57604453, COSV57604766; called by muse, mutect2, varscan2
- ARHGAP22 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV50937554; called by muse, mutect2, varscan2
- ARHGAP25 | c.1312C>T p.R438C (on ENST00000409202 / NM_001007231.3; = p.R430C on NM_014882.3) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767100810, COSV54900947; called by mutect2, varscan2
- ARHGAP27 | c.1622C>T p.S541L (on ENST00000428638 / NM_001282290.1; = p.S200L on NM_199282.3) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs937522899, COSV65357425; called by muse, mutect2, varscan2
- ARHGAP30 | c.2966G>A p.W989* (on ENST00000368013 / NM_001025598.2; = p.W778* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV63515799; called by muse, mutect2, varscan2
- ARHGDIG | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV51985705; called by muse, mutect2, varscan2
- ARHGEF16 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs559918389, COSV65681685; called by mutect2, varscan2
- ARHGEF6 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV51689224; called by muse, mutect2, varscan2
- ARID4A | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); catalogued as rs761464174, COSV62163001; called by mutect2, varscan2
- ARL13B | c.769T>G p.F257V (on ENST00000394222 / NM_001174150.2; = p.F150V on NM_144996.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV57397029, COSV57397376; called by muse, mutect2, varscan2
- ARMC12 | c.196G>T p.D66Y (on ENST00000373866 / NM_001286574.2; = p.D93Y on NM_145028.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55359951, COSV99849347; called by muse, mutect2, varscan2
- ARMC4 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745364784, COSV59460629; called by muse, mutect2, varscan2
- ARMCX6 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs975454410, COSV100726214, COSV62680680; called by muse, mutect2, varscan2
- ARMCX6 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100726216, COSV62680867; called by muse, mutect2, varscan2
- ARNT | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as COSV62230263; called by muse, mutect2, varscan2
- ARPP21 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868857967, COSV51795120; called by muse, mutect2, varscan2
- ARSD | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54198357; called by mutect2, varscan2
- ARSD | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1484967149, COSV99471974; called by muse, mutect2, varscan2
- ARSF | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764292225, COSV63839301; called by muse, mutect2, varscan2
- ARSI | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453092204, COSV60817140; called by muse, mutect2, varscan2
- ARSJ | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100192462; called by muse, mutect2, varscan2
- ASAP2 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV55629657; called by muse, mutect2, varscan2
- ASB17 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52409977; called by muse, varscan2
- ASIC2 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs780407455, COSV56758960; called by mutect2, varscan2
- ASPH | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs865991153, COSV65243991; called by muse, mutect2, varscan2
- ASPHD1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV58098541; called by muse, varscan2
- ASPSCR1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1369482681, COSV60728076; called by muse, mutect2, varscan2
- ASTN2 | c.1890-1G>A p.X630_splice (on ENST00000313400 / NM_001365069.1; = p.X579_splice on NM_014010.5) | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100524592, COSV57767113; called by muse, mutect2, varscan2
- ASXL1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60105800; called by muse, mutect2, varscan2
- ASXL3 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.978); catalogued as COSV52462652; called by muse, mutect2, varscan2
- ATG2A | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65966309; called by muse, mutect2, varscan2
- ATP10D | c.3889C>T p.P1297S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV56705878; called by mutect2, varscan2
- ATP11A | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1393278848, COSV52109350; called by muse, mutect2, varscan2
- ATP13A2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV58699631; called by muse, mutect2, varscan2
- ATP1A2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV63403193, COSV63404609; called by muse, mutect2, varscan2
- ATP1A3 | c.1406C>T p.S469F (on ENST00000545399 / NM_001256214.2; = p.S456F on NM_152296.5) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV57486578; called by muse, mutect2, varscan2
- ATP1A4 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63626045; called by muse, mutect2
- ATP2A1 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538702357, CM1411191, COSV62869021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by mutect2, varscan2
- ATP2C2 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52294335, COSV52299463; called by muse, mutect2, varscan2
- ATP6AP1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100645171; called by muse, mutect2, varscan2
- ATP6V0D2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.081); catalogued as rs778992470, COSV53414066; called by muse, mutect2, varscan2
- ATP7B | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54437082; called by mutect2, varscan2
- ATP8A1 | c.3299G>A p.G1100E | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.027); catalogued as COSV52532075; called by muse, mutect2, varscan2
- ATP8B1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1296782918, COSV52174246; called by mutect2, varscan2
- ATP8B2 | c.2389C>T p.H797Y (on ENST00000672630; = p.H764Y on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV59245008; called by muse, mutect2, varscan2
- ATP8B3 | c.3454G>A p.G1152S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59541667; called by muse, mutect2, varscan2
- ATPAF1 | c.973C>T p.Q325* (on ENST00000574428; = p.Q348* on NM_022745.4) | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV61304677; called by muse, mutect2, varscan2
- ATPSCKMT | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54726590; called by muse, mutect2, varscan2
- ATRN | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53526133; called by muse, mutect2, varscan2
- ATXN7L3 | c.482C>T p.P161L (on ENST00000389384 / NM_001382309.1; = p.P168L on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1402884103, COSV100115943, COSV60228563; called by muse, mutect2
- AWAT2 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.324); catalogued as rs1167762933, COSV52143120; called by muse, mutect2, varscan2
- AXDND1 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV62641316, COSV62645563; called by muse, mutect2
- B4GALNT3 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56751434; called by muse, mutect2, varscan2
- B4GALNT3 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV56751441; called by mutect2, varscan2
- BANF2 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55724108; called by muse, mutect2, varscan2
- BARX2 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV55649874; called by muse, mutect2
- BBS2 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs143607562; called by mutect2, varscan2
- BBS9 | c.2020C>T p.R674W (on ENST00000242067 / NM_001348036.1; = p.R634W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368526968; called by muse, mutect2, varscan2
- BCAS1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV65085082; called by muse, mutect2, varscan2
- BCL11A | c.1001C>T p.P334L (on ENST00000335712 / NM_001365609.1; = p.P368L on NM_018014.4) | Missense Mutation (SNP) | VAF 39/645 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1558613491, COSV59627503; called by muse, mutect2
- BCL11B | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1198790814, COSV61734821; called by muse, varscan2
- BCL6B | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53427263; called by muse, mutect2, varscan2
- BCO2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63062978; called by muse, mutect2, varscan2
- BCORL1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs267606346, COSV54393478, COSV99498287; called by mutect2, varscan2
- BCR | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV59929378; called by muse, varscan2
- BEND2 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66215488; called by muse, mutect2, varscan2
- BEST4 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV64733758; called by muse, mutect2, varscan2
- BICD2 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1279502533, COSV63548546; called by muse, mutect2
- BICRA | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV101194234; called by muse, mutect2
- BIRC6 | c.8704C>T p.R2902C | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs745413429, COSV70197632; called by muse, varscan2
- BLNK | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56410022; called by muse, mutect2
- BMP10 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV54894798; called by mutect2, varscan2
- BNIP5 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71325473; called by muse, mutect2, varscan2
- BPIFB2 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV50063691, COSV50065613; called by muse, varscan2
- BPIFC | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55911730; called by muse, mutect2, varscan2
- BPTF | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV58831921; called by muse, mutect2, varscan2
- BRD2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs779706920, COSV66372949; called by muse, mutect2, varscan2
- BRD4 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs200532628, COSV54584532; called by muse, mutect2, varscan2
- BRD4 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54584540; called by muse, mutect2, varscan2
- BRDT | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62863175; called by muse, mutect2, varscan2
- BRDT | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62864250; called by muse, mutect2, varscan2
- BRINP3 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1399315630, COSV66519115; called by muse, mutect2, varscan2
- BRWD3 | c.3247C>T p.Q1083* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV64746335; called by mutect2, varscan2
- BRWD3 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100955657; called by muse, mutect2, varscan2
- BSN | c.5531C>T p.A1844V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56515654; called by muse, mutect2, varscan2
- BSN | c.8407C>T p.P2803S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1430170463, COSV56515664; called by muse, mutect2
- BTAF1 | c.4495T>A p.F1499I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431935; called by muse, mutect2, varscan2
- BTBD10 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs757386788, COSV53398547; called by mutect2, varscan2
- BTBD6 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59267503; called by muse, mutect2, varscan2
- BTG3 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1217099989, COSV60286049; called by muse, mutect2, varscan2
- BTK | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV58118575; called by muse, mutect2, varscan2
- BTN1A1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV55067176; called by muse, mutect2, varscan2
- BTRC | c.1207C>T p.R403C (on ENST00000370187 / NM_033637.4; = p.R367C on NM_003939.5) | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV64579214; called by muse, mutect2, varscan2
- C10orf71 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV60504079; called by muse, mutect2
- C11orf53 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.06); catalogued as COSV54721205, COSV54721234; called by muse, mutect2, varscan2
- C14orf39 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs758496044, COSV58779694; called by mutect2, varscan2
- C19orf47 | c.248A>T p.N83I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63508778; called by mutect2, varscan2
- C1QB | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV59245202; called by muse, varscan2
- C1QTNF9 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752786322, COSV59656811; called by muse, mutect2, varscan2
- C1S | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61070583; called by muse, mutect2, varscan2
- C1S | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs782586920, COSV61070589; called by muse, mutect2, varscan2
- C1orf116 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV63943921; called by muse, mutect2, varscan2
- C1orf158 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1211233768, COSV55346261; called by muse, mutect2, varscan2
- C1orf94 | c.1794T>A p.F598L (on ENST00000488417 / NM_001134734.2; = p.F408L on NM_032884.5) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64913621; called by muse, mutect2, varscan2
- C2 | c.2194C>T p.L732F | Missense Mutation (SNP) | VAF 39/527 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs765593901, COSV100190658; called by muse, mutect2
- C2orf16 | c.4706C>T p.P1569L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62674789; called by muse, mutect2, varscan2
- C3 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99836087; called by muse, mutect2, varscan2
- C3 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV55571173; called by muse, mutect2, varscan2
- C3orf20 | c.2662C>T p.L888F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV53784187; called by mutect2, varscan2
- C3orf56 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV101228925, COSV67756148; called by muse, varscan2
- C3orf56 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.51); catalogued as COSV67756152; called by muse, varscan2
- C5AR1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV61892384; called by muse, mutect2, varscan2
- C6orf118 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57814016; called by muse, mutect2
- C6orf89 | c.685C>T p.P229S (on ENST00000373685; = p.P236S on NM_152734.4) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs962597318, COSV62101559; called by muse, mutect2
- C7 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs866073266, COSV57470115; called by muse, mutect2
- C7orf31 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs751938580, COSV52216736, COSV52220431; called by mutect2, varscan2
- C7orf31 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52216759; called by mutect2, varscan2
- C7orf57 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200648424, COSV62362364; called by mutect2, varscan2
- C9orf152 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as COSV68762797; called by muse, mutect2, varscan2
- CA12 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51604967; called by muse, mutect2, varscan2
- CA13 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs779439276, COSV58797391; called by mutect2, varscan2
- CACNA1A | c.3428C>T p.T1143I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV64194614; called by muse, mutect2, varscan2
- CACNA1A | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244229103, COSV64194624, COSV64216053; called by muse, varscan2
- CACNA1E | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV62383384; called by muse, mutect2, varscan2
- CACNA1E | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62388732; called by muse, varscan2
- CACNA1E | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62386290; called by muse, mutect2, varscan2
- CACNA1E | c.4456G>A p.A1486T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV62388802; called by muse, mutect2, varscan2
- CACNA1I | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV60804896; called by muse, varscan2
- CACNG5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.285); catalogued as COSV50057402; called by muse, mutect2
- CAD | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375233070; called by muse, mutect2, varscan2
- CAD | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53024726; called by muse, mutect2
- CALB1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.247); catalogued as rs778964362, COSV55367107; called by mutect2, varscan2
- CALCOCO1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV50412813; called by muse, mutect2, varscan2
- CAMTA1 | c.3899T>A p.L1300H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.043); catalogued as COSV57892702; called by muse, mutect2, varscan2
- CANT1 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV56605339; called by muse, mutect2, varscan2
- CAPN11 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV67237037; called by muse, varscan2
- CAPN2 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54335476; called by muse, mutect2, varscan2
- CAPN9 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55232443; called by muse, mutect2, varscan2
- CAPRIN1 | c.882T>G p.Y294* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV58219272; called by muse, mutect2, varscan2
- CAPSL | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs374502442; called by mutect2, varscan2
- CAPSL | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs145854210, COSV68437721; called by mutect2, varscan2
- CARD11 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as rs867239716, COSV62754120, COSV62755488; called by muse, mutect2, varscan2
- CARD11 | c.1572C>T p.A524= | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV62754775, COSV62755393; called by muse, mutect2, varscan2
- CARD11 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV62717069; called by muse, mutect2
- CARF | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV57546840; called by muse, mutect2
- CASK | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV59364469; called by muse, mutect2, varscan2
- CASZ1 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs776231987, COSV59734191; called by mutect2, varscan2
- CASZ1 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV59732548, COSV59734201; called by muse, mutect2
- CATSPERB | c.2955G>A p.L985= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56424596; called by mutect2, varscan2
- CBLC | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 78/680 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); catalogued as COSV54322029; called by muse, varscan2
- CBLL1 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as COSV56028577; called by mutect2, varscan2
- CCBE1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.024); catalogued as rs1381134355, COSV67949615; called by muse, mutect2
- CCDC27 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1055191206, COSV53899453; called by muse, mutect2, varscan2
- CCDC86 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753482209, COSV57124852; called by muse, mutect2, varscan2
- CCDC88C | c.4203G>A p.K1401= | Splice Region (SNP) | VAF 34/232 reads (15%) | catalogued as rs756684531, COSV58661131; called by muse, varscan2
- CCDC88C | c.3085G>A p.G1029R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs1184281643, COSV66236887; called by muse, mutect2, varscan2
- CCN4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as rs760043627, COSV51530809; called by mutect2, varscan2
- CCNE1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1449890888, COSV52904016; called by muse, mutect2, varscan2
- CCNJL | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs1368261544, COSV57444190; called by muse, mutect2, varscan2
- CCNT2 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV51472212; called by mutect2, varscan2
- CCR5 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV52751305; called by mutect2, varscan2
- CCSER1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV61420987; called by muse, mutect2, varscan2
- CD101 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.368); catalogued as COSV56717297, COSV56718974; called by muse, mutect2, varscan2
- CD14 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57370535; called by mutect2, varscan2
- CD1A | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56861132; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD300A | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV60411092; called by muse, mutect2, varscan2
- CD300E | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.589); catalogued as COSV60790231; called by muse, varscan2
- CD300LB | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.129); catalogued as COSV58725444; called by muse, mutect2
- CD300LB | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV58725453; called by muse, varscan2
- CD33 | c.840C>T p.F280= | Splice Region (SNP) | VAF 11/52 reads (21%) | catalogued as COSV51800871; called by muse, mutect2, varscan2
- CD33 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs749574667, COSV51800886; called by mutect2, varscan2
- CD38 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as rs1393490181, COSV56889281; called by muse, mutect2, varscan2
- CD55 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs12135160, COSV58576732; called by mutect2, varscan2
- CD5L | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs200057023, COSV63821588; called by muse, mutect2, varscan2
- CD6 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV57837101; called by muse, varscan2
- CD99L2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60935576, COSV60936962; called by muse, mutect2, varscan2
- CDC42BPG | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV61346581; called by muse, mutect2, varscan2
- CDCA7 | c.1048T>G p.Y350D (on ENST00000347703 / NM_145810.3; = p.Y429D on NM_031942.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV60720181; called by muse, mutect2, varscan2
- CDCA7L | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs1240634203, COSV62258648; called by mutect2, varscan2
- CDH20 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.493); catalogued as COSV53007701; called by muse, mutect2, varscan2
- CDH4 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100848434; called by muse, varscan2
- CDH4 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760758114, COSV64648275, COSV64654891; called by muse, mutect2, varscan2
- CDH5 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV58515944; called by mutect2, varscan2
- CDH6 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV54067384; called by muse, mutect2, varscan2
- CDHR3 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58415599; called by muse, mutect2, varscan2
- CDK5RAP3 | c.890T>C p.F297S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58114662; called by muse, mutect2, varscan2
- CDKL5 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV66110766; called by muse, mutect2, varscan2
- CEACAM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV50726152; called by muse, mutect2
- CEACAM1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV50726193; called by muse, mutect2, varscan2
- CEACAM19 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 72/631 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1405479240, COSV62551912; called by muse, varscan2
- CEACAM20 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV57601252; called by muse, mutect2, varscan2
- CEACAM3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV55761221; called by muse, varscan2
- CEACAM5 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 27/532 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55751589; called by muse, mutect2
- CECR2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52839165; called by muse, mutect2, varscan2
- CECR2 | c.1825G>A p.D609N (on ENST00000342247 / NM_001290047.2; = p.D426N on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs141453031; called by mutect2, varscan2
- CELF3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778026308, COSV51881488; called by muse, mutect2, varscan2
- CELSR2 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 47/869 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV54769219; called by muse, mutect2
- CELSR2 | c.5879C>T p.P1960L | Missense Mutation (SNP) | VAF 91/462 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54769241; called by muse, mutect2, varscan2
- CELSR2 | c.6818C>T p.P2273L | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54769251; called by muse, mutect2, varscan2
- CEMIP | c.3758G>A p.G1253E | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238586560, COSV54990383; called by muse, mutect2
- CEP152 | c.2110C>T p.L704F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858337; called by mutect2, varscan2
- CEP70 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV53875029; called by muse, mutect2
- CERKL | c.1454C>T p.P485L (on ENST00000339098 / NM_001030311.2; = p.P459L on NM_201548.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV59205828; called by muse, mutect2, varscan2
- CERS5 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1167444903, COSV100451906; called by muse, mutect2
- CERS5 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58188793; called by muse, mutect2
- CFAP221 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763821756, COSV54655207; called by mutect2, varscan2
- CFAP251 | c.3302G>A p.G1101E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV56609464; called by muse, mutect2
- CFAP43 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1007247227, COSV100829035, COSV63852676; called by muse, mutect2, varscan2
- CFAP43 | c.2057T>A p.I686N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53377279; called by muse, mutect2, varscan2
- CFAP65 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs202017377, COSV55389926, COSV99838406; called by muse, mutect2, varscan2
- CFAP65 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.921); catalogued as rs747643054, COSV99838231; called by muse, mutect2, varscan2
- CFAP91 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1171856021, COSV56340212; called by muse, mutect2
- CFTR | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as COSV50046228; called by mutect2, varscan2
- CHAC1 | c.456C>A p.Y152* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV71436025; called by muse, mutect2
- CHAF1A | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs753346844, COSV56671403; called by muse, mutect2, varscan2
- CHAT | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60322756; called by muse, mutect2, varscan2
- CHD4 | c.4151A>T p.D1384V (on ENST00000357008 / NM_001363606.2; = p.D1397V on NM_001273.5) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58898137; called by muse, mutect2, varscan2
- CHD5 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1424567700, COSV52411841; called by muse, mutect2, varscan2
- CHD6 | c.7619C>T p.P2540L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1185661304, COSV64689502; called by muse, mutect2
- CHD7 | c.4070C>T p.S1357F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71108789, COSV71113692; called by muse, mutect2
- CHI3L1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.705); catalogued as rs896560392, COSV55137495; called by muse, mutect2, varscan2
- CHRM1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV61006477; called by muse, mutect2, varscan2
- CHRM3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs768152496, COSV55085839; called by mutect2, varscan2
- CHRM3 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55085856; called by muse, mutect2, varscan2
- CHRNA7 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180852; called by mutect2, varscan2
- CHRNA9 | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV59574046; called by muse, mutect2, varscan2
- CHST15 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.086); catalogued as COSV60561278; called by muse, mutect2, varscan2
- CHST15 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs1337191771, COSV60561288; called by muse, mutect2, varscan2
- CIAPIN1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV67953275; called by muse, mutect2, varscan2
- CIART | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51743733; called by muse, varscan2
- CIART | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs781844173, COSV51743745; called by muse, mutect2, varscan2
- CIB3 | c.100T>C p.Y34H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99521695; called by muse, mutect2, varscan2
- CIITA | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs954347047, COSV100162279, COSV60855908; called by muse, varscan2
- CILK1 | c.1604C>T p.S535F (on ENST00000350082 / NM_001375397.1; = p.S528F on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV63153882; called by mutect2, varscan2
- CILP | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1474729251, COSV56023095; called by muse, varscan2
- CIT | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55865176; called by muse, mutect2, varscan2
- CKAP5 | c.5629C>T p.Q1877* (on ENST00000529230 / NM_001008938.4; = p.Q1817* on NM_014756.3) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV56366071; called by muse, mutect2, varscan2
- CLASP1 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV55320011; called by muse, mutect2, varscan2
- CLASRP | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1410706185, COSV55515466; called by muse, mutect2, varscan2
- CLCN3 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs375181512; called by mutect2, varscan2
- CLCN3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.697); catalogued as rs143120417; called by mutect2, varscan2
- CLDN14 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772784; called by muse, mutect2, varscan2
- CLDN18 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs759969828, COSV99480609; called by mutect2, varscan2
- CLDN2 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61020738; called by muse, mutect2, varscan2
- CLEC17A | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as COSV60427305; called by muse, mutect2, varscan2
- CLEC3A | c.304G>A p.E102K (on ENST00000651443; = p.E93K on NM_005752.6) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV55219897, COSV55220898; called by mutect2, varscan2
- CLEC4M | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV50217505; called by muse, mutect2, varscan2
- CLEC5A | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.931); catalogued as COSV69397038; called by muse, mutect2, varscan2
- CLHC1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.266); catalogued as COSV68463905; called by muse, mutect2, varscan2
- CLMN | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV54180962; called by muse, mutect2
- CLN3 | c.551C>T p.S184F (on ENST00000360019 / NM_001286104.2; = p.S208F on NM_000086.2) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61105513; called by mutect2, varscan2
- CLSPN | c.3167A>G p.D1056G | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV52048995; called by muse, mutect2, varscan2
- CLSTN2 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV71719815; called by muse, mutect2
- CLTCL1 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54228069; called by muse, mutect2, varscan2
- CLVS1 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as COSV57973086; called by muse, mutect2, varscan2
- CNDP1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV62593546; called by muse, mutect2
- CNDP1 | c.923A>T p.N308I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV62593551; called by muse, mutect2, varscan2
- CNGB1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); catalogued as COSV51899432; called by muse, mutect2, varscan2
- CNPPD1 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs779541136, COSV55406271; called by mutect2, varscan2
- CNTN4 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61870902; called by muse, mutect2, varscan2
- CNTNAP1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1399802501, COSV52849153; called by mutect2, varscan2
- COA8 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56027897; called by muse, mutect2, varscan2
- COBLL1 | c.1337C>T p.P446L (on ENST00000392717; = p.P408L on NM_014900.5) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV52065742; called by muse, mutect2, varscan2
- COG5 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51747262; called by muse, mutect2
- COL11A1 | c.4405G>A p.E1469K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100614372, COSV62178813; called by muse, varscan2
- COL11A1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as COSV100616048, COSV62190243; called by muse, mutect2, varscan2
- COL11A2 | c.3662C>T p.P1221L (on ENST00000341947 / NM_080680.3; = p.P1114L on NM_080679.2) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1562323483, COSV59495511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.091); catalogued as COSV59495519; called by muse, mutect2, varscan2
- COL15A1 | c.1354-1G>A p.X452_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as COSV66643156; called by muse, mutect2, varscan2
- COL1A1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56803590; called by muse, mutect2, varscan2
- COL1A1 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as rs772929903, COSV56803596; ClinVar: uncertain significance; called by mutect2, varscan2
- COL1A2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as COSV51955919; called by muse, mutect2, varscan2
- COL1A2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51956755; called by muse, mutect2, varscan2
- COL1A2 | c.2782-1G>A p.X928_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV51954245, COSV51955929; called by muse, mutect2, varscan2
- COL22A1 | c.4204G>A p.G1402S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57331166; called by muse, mutect2, varscan2
- COL22A1 | c.3666G>A p.G1222= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV57331173; called by muse, mutect2, varscan2
- COL25A1 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 33/101 reads (33%) | catalogued as COSV101211202; called by muse, mutect2, varscan2
- COL3A1 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.095); catalogued as COSV58585285; called by muse, mutect2
- COL4A2 | c.4175G>A p.G1392E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV64626938; called by muse, mutect2, varscan2
- COL4A3 | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67414610; called by muse, mutect2, varscan2
- COL4A4 | c.4144C>T p.P1382S | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV61631041; called by muse, varscan2
- COL4A4 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV61631048; called by muse, mutect2, varscan2
- COL4A4 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs754398956, COSV61630234, COSV61630282; ClinVar: uncertain significance; called by muse, mutect2
- COL4A5 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60357631, COSV60372469; called by muse, mutect2
- COL4A6 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329799694, COSV57863046; called by muse, mutect2, varscan2
- COL4A6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV57863059; called by muse, mutect2, varscan2
- COL5A1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs897885276, COSV65667631; called by muse, mutect2, varscan2
- COL5A3 | c.4712C>T p.S1571L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV53408847; called by muse, mutect2, varscan2
- COL5A3 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs367849087; called by mutect2, varscan2
- COL5A3 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53408881; called by muse, mutect2, varscan2
- COL6A3 | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV55085441; called by muse, mutect2, varscan2
- COL6A3 | c.3016C>T p.H1006Y | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV55085448; called by muse, mutect2
- COL6A3 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs780115806, COSV55085489; called by mutect2, varscan2
- COL6A6 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); catalogued as COSV62021933; called by muse, mutect2, varscan2
- COL7A1 | c.7868G>A p.G2623D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as CM071644, CM083610, COSV56476314; called by muse, mutect2, varscan2
- COL7A1 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs146418495; called by mutect2, varscan2
- COL7A1 | c.4564-1G>A p.X1522_splice | Splice Site (SNP) | VAF 15/96 reads (16%) | catalogued as COSV60393718; called by muse, mutect2, varscan2
- COL9A2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs761059218, COSV65607352; called by muse, mutect2, varscan2
- COL9A3 | c.345G>A p.G115= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as rs1385900961, COSV59651753, COSV59651999; called by muse, mutect2
- COLQ | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67524485; called by muse, mutect2
- COPS6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV57995409; called by muse, mutect2, varscan2
- COQ8B | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs756079490, COSV54574086; called by muse, mutect2, varscan2
- COX8A | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV58478706; called by muse, mutect2, varscan2
- CPA5 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201205923; called by muse, mutect2, varscan2
- CPA6 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.406); catalogued as rs1018666393, COSV52719710, COSV52732409; called by muse, mutect2, varscan2
- CPAMD8 | c.3949C>T p.P1317S (on ENST00000651564; = p.P1270S on NM_015692.5) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.79); catalogued as COSV71596358; called by muse, mutect2, varscan2
- CPAMD8 | c.3491G>A p.R1164Q (on ENST00000651564; = p.R1117Q on NM_015692.5) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs1315391248, COSV71596360; called by muse, mutect2, varscan2
- CPAMD8 | c.1904C>T p.S635L (on ENST00000651564; = p.S588L on NM_015692.5) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV52233037; called by muse, mutect2, varscan2
- CPEB2 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52590642; called by muse, mutect2, varscan2
- CPNE5 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55195750; called by mutect2, varscan2
- CPNE9 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56068139; called by muse, mutect2
- CPZ | c.1713G>A p.M571I (on ENST00000360986 / NM_001014447.3; = p.M560I on NM_003652.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV59922401; called by muse, mutect2
- CRACD | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.389); catalogued as COSV51718786; called by muse, mutect2, varscan2
- CRACDL | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.136); catalogued as COSV67407400; called by muse, mutect2
- CRB1 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV66329365; called by muse, mutect2, varscan2
- CRB1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs986645649, COSV66328552; called by muse, varscan2
- CREBBP | c.5333C>T p.S1778L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs1220965943, COSV52115130, COSV99268481; called by muse, mutect2
- CREBBP | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV52119166; called by muse, mutect2
- CRIPT | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53231526; called by muse, mutect2, varscan2
- CRY2 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752643640, COSV69888470; called by mutect2, varscan2
- CSMD2 | c.9805C>T p.P3269S | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53899278; called by muse, mutect2, varscan2
- CSMD2 | c.7075G>A p.E2359K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV53899341; called by muse, mutect2, varscan2
- CSNK1A1L | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs867623107, COSV65789536; called by mutect2, varscan2
- CSRP3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56390593; called by muse, mutect2
- CTC1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100236155; called by mutect2, varscan2
- CTCFL | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452421283, COSV54772844; called by muse, mutect2, varscan2
- CTIF | c.1734G>C p.W578C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56482011, COSV56490377; called by muse, mutect2, varscan2
- CTNND2 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs867204139, COSV58867189; called by muse, mutect2
- CTNND2 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs769876996, COSV58878070; called by muse, mutect2, varscan2
- CTPS2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63721907; called by muse, mutect2, varscan2
- CTR9 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63728271; called by muse, mutect2
- CTTNBP2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | catalogued as COSV50394335; called by muse, mutect2
- CTTNBP2 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1469967110, COSV99355138; called by muse, mutect2
- CUEDC1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs1325850990, COSV64226253; called by muse, mutect2, varscan2
- CUL3 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52363201; called by muse, mutect2, varscan2
- CWC22 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV55426215; called by muse, mutect2, varscan2
- CXCR2 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280314; called by muse, mutect2, varscan2
- CXCR6 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as COSV56115107; called by muse, mutect2, varscan2
- CYFIP2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.901); catalogued as rs1411083790, COSV59033481; called by muse, mutect2
- CYFIP2 | c.2305C>T p.R769C (on ENST00000616178 / NM_001291722.2; = p.R744C on NM_014376.4) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770698075, COSV59033852; called by muse, mutect2, varscan2
- CYP11A1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV51431443; called by muse, mutect2
- CYP17A1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV64004825; called by muse, mutect2, varscan2
- CYP27C1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV58866566; called by muse, mutect2, varscan2
- CYP2A6 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV56534670; called by muse, mutect2, varscan2
- CYP2F1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV58526711; called by muse, mutect2, varscan2
- CYP4A22 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs373881337; called by mutect2, varscan2
- CYP4A22 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.26); catalogued as COSV53739513; called by muse, mutect2, varscan2
- CYP4A22 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs767886913, COSV53738388; called by muse, mutect2, varscan2
- CYP4F22 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV99512505; called by muse, mutect2, varscan2
- CYP4X1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV64149879; called by muse, mutect2, varscan2
- CYTH3 | c.958G>A p.E320K (on ENST00000396741; = p.E319K on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV60359092; called by muse, mutect2, varscan2
- DAAM1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs767797655, COSV62834416; called by muse, mutect2, varscan2
- DACH1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57495211; called by muse, mutect2, varscan2
- DAND5 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV57684031; called by muse, mutect2, varscan2
- DAW1 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100005855; called by muse, mutect2, varscan2
- DCAF12L1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs757868620, COSV64421493, COSV64422607; called by muse, varscan2
- DCAF12L1 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV64421504; called by muse, varscan2
- DCAF6 | c.1934C>T p.S645F (on ENST00000312263 / NM_001349778.1; = p.S665F on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV56577156; called by mutect2, varscan2
- DCD | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV53201388; called by mutect2, varscan2
- DCDC1 | c.2663G>A p.W888* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60305182; called by muse, mutect2, varscan2
- DCP1B | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54968289; called by muse, mutect2, varscan2
- DCST1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV55057796; called by muse, mutect2
- DCST2 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55050940; called by muse, mutect2, varscan2
- DDI1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1238025599, COSV56373822; called by muse, mutect2
- DDX23 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV57282721; called by muse, mutect2, varscan2
- DDX5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56748670; called by muse, mutect2, varscan2
- DDX53 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV60068778; called by mutect2, varscan2
- DDX56 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs556884834, COSV51835960; called by mutect2, varscan2
- DDX59 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV58751405; called by muse, mutect2, varscan2
- DDX60 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67095994; called by mutect2, varscan2
- DEGS1 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV60378932; called by muse, mutect2, varscan2
- DENND1C | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV57568260; called by mutect2, varscan2
- DENND2C | c.1634C>T p.S545L (on ENST00000393274 / NM_001256404.2; = p.S488L on NM_198459.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV67920999; called by muse, mutect2, varscan2
- DENND2C | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs200569570, COSV67920813; called by mutect2, varscan2
- DENND3 | c.3098G>A p.G1033D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1471216027, COSV52801904; called by muse, mutect2, varscan2
- DENND4B | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV63408189; called by muse, mutect2
- DEPP1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53573776; called by muse, mutect2, varscan2
- DFFA | c.778T>A p.L260M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65477304; called by muse, mutect2
- DFFB | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58860634; called by muse, mutect2, varscan2
- DGKA | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs755213694, COSV59385431; called by muse, mutect2, varscan2
- DHRS3 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66108075; called by muse, mutect2, varscan2
- DHRS7B | c.331T>A p.L111M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100683866; called by mutect2, varscan2
- DHX16 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs1291336952, COSV53313310; called by muse, mutect2
- DHX35 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52669156; called by muse, mutect2, varscan2
- DHX37 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438972; called by muse, mutect2
- DHX57 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54883930; called by muse, mutect2, varscan2
- DHX57 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV54883944; called by muse, mutect2, varscan2
- DIDO1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV56618385; called by muse, mutect2, varscan2
- DIO3 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV63773322; called by muse, varscan2
- DISP1 | c.4072C>T p.H1358Y | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1246547595, COSV52657167; called by muse, mutect2
- DISP3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as COSV53823260, COSV53824664; called by muse, mutect2, varscan2
- DMBT1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.759); catalogued as COSV57539831; called by muse, mutect2, varscan2
- DMBT1 | c.3066G>A p.W1022* (on ENST00000338354 / NM_001377530.1; = p.W523* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 42/397 reads (11%) | catalogued as COSV57539277; called by muse, mutect2, varscan2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by mutect2, varscan2
- DMD | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55863356; called by muse, mutect2, varscan2
- DMKN | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.814); catalogued as rs1449839918, COSV100303222; called by muse, mutect2
- DMKN | c.919-1G>A p.X307_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as rs1314336454, COSV100303226; called by muse, mutect2
- DMRT2 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.139); catalogued as COSV52401468; called by muse, mutect2, varscan2
- DMWD | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs762042225, COSV52175510, COSV52176997; called by mutect2, varscan2
- DMXL2 | c.4108C>T p.H1370Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1444368024, COSV99195972; called by muse, mutect2, varscan2
- DNAAF1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV57576855; called by muse, mutect2, varscan2
- DNAH1 | c.5428C>T p.P1810S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776970930, COSV70227861; called by muse, mutect2, varscan2
- DNAH10 | c.6082G>A p.E2028K (on ENST00000409039; = p.E1967K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68991254; called by muse, mutect2, varscan2
- DNAH11 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV60949982; called by muse, mutect2, varscan2
- DNAH17 | c.9998C>T p.S3333L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766534694, COSV67751811; called by mutect2, varscan2
- DNAH17 | c.5507C>T p.S1836F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67751930; called by muse, mutect2, varscan2
- DNAH2 | c.10172G>A p.W3391* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV66718342; called by muse, varscan2
- DNAH3 | c.10232C>T p.A3411V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as COSV54514027, COSV54542400; called by muse, mutect2, varscan2
- DNAH3 | c.8252G>A p.G2751E | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54514101; called by muse, mutect2, varscan2
- DNAH3 | c.8132C>T p.S2711F | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54514127; called by muse, varscan2
- DNAH5 | c.11962G>A p.D3988N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770036339, COSV54216273; called by mutect2, varscan2
- DNAH5 | c.9667G>A p.E3223K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54216325; called by muse, mutect2, varscan2
- DNAH5 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs764244707, COSV54216373; called by muse, mutect2, varscan2
- DNAH8 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1253355621, COSV59436638; called by muse, mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DNAH9 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52344009; called by muse, mutect2
- DNAI1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54280130; called by muse, mutect2, varscan2
- DNAI2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV56757173; called by muse, mutect2, varscan2
- DNAJB7 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV53421439, COSV53421999; called by muse, mutect2
- DNAJB8 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV59878436; called by muse, varscan2
- DNAJC12 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV56547528; called by muse, mutect2, varscan2
- DNAJC5B | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52536698; called by muse, mutect2, varscan2
- DNAJC6 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV54772871; called by muse, mutect2
- DNMT3B | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52416919; called by muse, varscan2
- DOCK7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV52001441; called by muse, mutect2, varscan2
- DOK5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765612921, COSV52817152; called by mutect2, varscan2
- DOP1B | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757367283, COSV67692859; called by mutect2, varscan2
- DPP9 | c.365C>T p.S122F (on ENST00000598800; = p.S151F on NM_139159.5) | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53590468; called by muse, mutect2, varscan2
- DPYSL2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as rs781052884, COSV60782004; called by mutect2, varscan2
- DRAXIN | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.187); catalogued as rs200827019, COSV53842625; called by mutect2, varscan2
- DRC7 | c.1112G>A p.W371* | Nonsense Mutation (SNP) | VAF 15/161 reads (9%) | catalogued as rs1427437056, COSV61053991; called by muse, mutect2
- DRC7 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61053993; called by muse, mutect2
- DRC7 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as COSV61053999; called by muse, mutect2
- DRD5 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58577486; called by muse, varscan2
- DSC1 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937183; called by muse, mutect2, varscan2
- DSE | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs772848000, COSV59062910; called by mutect2, varscan2
- DSG3 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs747842021, COSV57125290; called by mutect2, varscan2
- DSP | c.6635G>A p.G2212E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65792198; called by muse, mutect2, varscan2
- DSP | c.8582C>T p.S2861F | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.451); catalogued as rs1269834512, COSV60939123, COSV60941061; called by muse, mutect2, varscan2
- DSTYK | c.2246T>C p.L749P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100904468; called by muse, mutect2, varscan2
- DTWD1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1037465844, COSV52071402; called by muse, mutect2, varscan2
- DTX2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs760694781, COSV56859908; called by muse, mutect2, varscan2
- DUSP10 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60457247, COSV60458990; called by muse, mutect2, varscan2
- DUXA | c.439-2A>G p.X147_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101617121; called by muse, mutect2, varscan2
- DYNC1H1 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs1060502206, COSV64135811; ClinVar: uncertain significance; called by muse, varscan2
- DYNC1H1 | c.8842C>T p.R2948C | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64135820; called by muse, mutect2, varscan2
- DYNC1H1 | c.10681C>T p.R3561C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV64135825; called by muse, varscan2
- DYSF | c.5186C>T p.S1729F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV50290279; called by muse, mutect2, varscan2
- EBF2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV68776991; called by muse, mutect2, varscan2
- EBF3 | c.1048G>A p.E350K (on ENST00000355311 / NM_001375392.1; = p.E341K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62472936, COSV62473660; called by muse, mutect2
- EBF3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100798941, COSV62473667; called by muse, mutect2
- ECEL1 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV58811754; called by muse, mutect2
- EEFSEC | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1341990877, COSV54623800; called by muse, mutect2
- EEFSEC | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV54623823, COSV99631230; called by muse, mutect2, varscan2
- EFCAB12 | c.1461G>A p.R487= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as rs781463369, COSV58175595; called by mutect2, varscan2
- EFCAB13 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144068587; called by mutect2, varscan2
- EFCAB3 | c.659T>G p.F220C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.436); catalogued as COSV59500913; called by muse, mutect2, varscan2
- EFCAB6 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53061028; called by muse, mutect2, varscan2
- EGFL6 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63633480, COSV63635058; called by muse, mutect2, varscan2
- EGFLAM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV59297844; called by muse, varscan2
- EGR4 | c.730C>T p.P244S (on ENST00000545030; = p.P141S on NM_001965.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.157); catalogued as COSV71531984; called by muse, mutect2, varscan2
- EIF2D | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV55113127; called by muse, varscan2
- EIF4G1 | c.1033C>T p.L345F (on ENST00000346169 / NM_198241.3; = p.L149F on NM_004953.5) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs1251323549, COSV59989114; called by muse, mutect2
- ELL | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs964006105, COSV53215198; called by muse, mutect2, varscan2
- ELMO1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60300577; called by muse, mutect2, varscan2
- ELMOD3 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 35/170 reads (21%) | catalogued as rs562825417, COSV59772043; called by muse, mutect2, varscan2
- ELOVL4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs532735834, COSV63953631; called by mutect2, varscan2
- EMID1 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61828990; called by muse, mutect2, varscan2
- EMID1 | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61828997; called by muse, mutect2
- EMILIN3 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753687591, COSV60035687; called by mutect2, varscan2
- ENDOD1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53589189; called by muse, mutect2, varscan2
- ENGASE | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs762111541, COSV56135016; called by muse, mutect2, varscan2
- ENPP3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV62953751; called by mutect2, varscan2
- ENPP7 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV60386085; called by muse, mutect2, varscan2
- EPB41L3 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs867440484, COSV59449092; called by muse, mutect2, varscan2
- EPB41L3 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59446189; called by muse, mutect2, varscan2
- EPCAM | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1008677622, COSV55392776; called by muse, mutect2, varscan2
- EPG5 | c.7510C>T p.R2504C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921463655, COSV56347755, COSV99957591; called by muse, mutect2, varscan2
- EPG5 | c.6589C>T p.L2197F | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV56347780; called by muse, mutect2
- EPHA3 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753700696, COSV60696515, COSV60700528; called by mutect2, varscan2
- EPHA4 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.259); catalogued as rs1307844419, COSV56030076; called by muse, varscan2
- EPHB3 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57805237; called by muse, mutect2, varscan2
- EPHB4 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62268487; called by muse, mutect2
- EPPK1 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV73261023; called by muse, mutect2
- EPS15L1 | c.996A>C p.Q332H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50167928; called by mutect2, varscan2
- EPS8L3 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV62609160; called by muse, mutect2, varscan2
- EPS8L3 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV100719664; called by muse, mutect2
- ERBB4 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61470732, COSV61477984; called by muse, mutect2, varscan2
- ERBB4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs769311799, COSV53519461; called by mutect2, varscan2
- ERC2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV55612384; called by muse, mutect2
- ERICH1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50637651; called by muse, varscan2
- ERN1 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV70501363; called by muse, mutect2, varscan2
- ESPNL | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs766181578, COSV58033698; called by muse, mutect2, varscan2
- ESRP1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs983868029, COSV64408801; called by muse, mutect2
- ETV6 | c.236T>C p.L79S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67149104, COSV67151110; called by muse, mutect2, varscan2
- EVC2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV60390936; called by muse, mutect2, varscan2
- EWSR1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as COSV58421598, COSV58426314; called by muse, mutect2, varscan2
- EXOC6 | c.1940T>G p.F647C | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53322247; called by muse, mutect2
- EXOC7 | c.1595C>T p.S532L (on ENST00000335146 / NM_001145297.4; = p.S450L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs773783577, COSV58035546; called by mutect2, varscan2
- EXOSC10 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 37/123 reads (30%) | catalogued as rs760850094, COSV58663698; called by muse, mutect2, varscan2
- EYA2 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100426516; called by muse, varscan2
- EYA3 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as rs964909906, COSV65816230; called by mutect2, varscan2
- EZH1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777686988, COSV70549056; called by mutect2, varscan2
- F8 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64271589; called by muse, mutect2, varscan2
- F8 | c.302A>C p.D101A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM960539, CM980665, COSV64271594; called by muse, mutect2, varscan2
- F9 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs866507797, COSV54379588; called by muse, mutect2, varscan2
- FAM117B | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57417833; called by muse, mutect2
- FAM135B | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52716564; called by muse, varscan2
- FAM13C | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV53246200; called by muse, mutect2, varscan2
- FAM155A | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV65556567; called by muse, mutect2, varscan2
- FAM167A | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs770696934, COSV52668352; called by mutect2, varscan2
- FAM170A | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as rs1188928431, COSV58924694; called by muse, mutect2, varscan2
- FAM171A1 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.197); catalogued as COSV65315150; called by muse, mutect2, varscan2
- FAM210A | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV59183891; called by muse, mutect2, varscan2
- FAM217A | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV51159487; called by muse, mutect2, varscan2
- FAM24A | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64405875; called by muse, mutect2, varscan2
- FAM3B | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754894265, COSV63613649; called by mutect2, varscan2
- FAM3B | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as rs747932044, COSV100783713; called by mutect2, varscan2
- FAM47C | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs782773475, COSV63725526; called by muse, mutect2, varscan2
- FAM71A | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs865812216, COSV54234581; called by muse, mutect2, varscan2
- FAM83C | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV65582607; called by muse, mutect2
- FAM83F | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.116); catalogued as rs1182739494, COSV60999882; called by muse, mutect2
- FANCM | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57499585; called by muse, mutect2
- FARSA | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV58904659; called by muse, mutect2, varscan2
- FASLG | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60679987; called by muse, mutect2
- FASLG | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60679994; called by muse, varscan2
- FASN | c.5749C>T p.R1917C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367771241, COSV60752621; called by muse, mutect2
- FASTKD5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760731320, COSV53905290; called by mutect2, varscan2
- FAT1 | c.7442C>T p.T2481I | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV71673278; called by muse, mutect2, varscan2
- FAT1 | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV71673280; called by muse, mutect2, varscan2
- FAT1 | c.5084C>T p.S1695L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71673281, COSV71675655; called by muse, mutect2, varscan2
- FAT2 | c.8767G>A p.E2923K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); catalogued as rs777011886, COSV55816581; called by muse, mutect2, varscan2
- FAT3 | c.3520G>A p.D1174N | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53095477; called by muse, varscan2
- FAT3 | c.4832G>A p.G1611E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV53095500; called by muse, varscan2
- FAT4 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67883817; called by muse, mutect2, varscan2
- FAT4 | c.10351G>A p.E3451K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV58678810; called by muse, mutect2, varscan2
- FATE1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.722); catalogued as COSV64848910, COSV64849232; called by muse, mutect2, varscan2
- FAXC | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as COSV67601852; called by muse, mutect2, varscan2
- FBLN1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as rs755803565, COSV53045623; called by muse, mutect2, varscan2
- FBLN5 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV50902734; called by muse, mutect2, varscan2
- FBN3 | c.3962-1G>A p.X1321_splice | Splice Site (SNP) | VAF 11/73 reads (15%) | catalogued as COSV54457554; called by mutect2, varscan2
- FBN3 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54457563; called by muse, mutect2, varscan2
- FBXL13 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50864415; called by muse, mutect2, varscan2
- FBXO11 | c.323C>T p.P108L (on ENST00000403359 / NM_001190274.2; = p.P24L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs1232093891, COSV57018068; called by muse, mutect2, varscan2
- FBXO42 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65045273; called by muse, mutect2
- FCAMR | c.1471G>A p.E491K (on ENST00000324852 / NM_001170631.2; = p.M223I on NM_032029.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs372937296; called by mutect2, varscan2
- FCGBP | c.9169G>A p.E3057K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs767091879; called by muse, mutect2, varscan2
- FCHSD2 | c.2102G>A p.R701K | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV60808193; called by muse, mutect2
- FCRL3 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as rs575879706, COSV63840625, COSV63844510; called by mutect2, varscan2
- FCRL4 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV54861340; called by muse, mutect2, varscan2
- FCRL5 | c.2753G>A p.R918K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV62513196; called by muse, mutect2, varscan2
- FCRL6 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV58940726; called by muse, mutect2, varscan2
- FDX2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474921770, COSV58532768; called by muse, mutect2, varscan2
- FER1L6 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67549190; called by muse, mutect2, varscan2
- FETUB | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV54005277; called by muse, mutect2, varscan2
- FGA | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs754678681, COSV57394819; called by mutect2, varscan2
- FGD6 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs781518975, COSV59691922; called by mutect2, varscan2
- FGFR2 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.425); catalogued as COSV60644192; called by mutect2, varscan2
- FGFR2 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 11/93 reads (12%) | catalogued as COSV60644205; called by muse, mutect2, varscan2
- FGR | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs758058977, COSV64969410; called by muse, mutect2, varscan2
- FHOD3 | c.2282C>T p.S761F (on ENST00000359247 / NM_001281739.3; = p.S778F on NM_025135.5) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.188); catalogued as COSV57162889, COSV57169913; called by muse, mutect2, varscan2
- FILIP1 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52726579; called by muse, mutect2, varscan2
- FILIP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52726622; called by muse, varscan2
- FLG | c.9638C>T p.S3213F | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV64239810; called by muse, mutect2
- FLG | c.7075G>A p.G2359R | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as COSV100910533; called by muse, mutect2, varscan2
- FLG | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.459); catalogued as rs369816027, COSV100910493; called by muse, mutect2, varscan2
- FLG | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV64239842; called by muse, mutect2, varscan2
- FLG2 | c.6407C>T p.S2136L | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66167698; called by muse, mutect2, varscan2
- FLNB | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1290855363, COSV55875664; called by muse, mutect2, varscan2
- FLNB | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV55875700; called by muse, mutect2
- FLNC | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV57953664; called by muse, mutect2, varscan2
- FLNC | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746217788, COSV57953671; called by muse, mutect2, varscan2
- FLRT1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748337416, COSV55358871; called by mutect2, varscan2
- FLRT2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58138366; called by muse, mutect2, varscan2
- FLT3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54049633; called by muse, mutect2, varscan2
- FLVCR1 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV65323340; called by mutect2, varscan2
- FMN2 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100142894, COSV100144053; called by muse, mutect2, varscan2
- FN1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201876289, COSV100115858, COSV60547906; called by mutect2, varscan2
- FNDC11 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.006); catalogued as COSV64442650; called by muse, mutect2
- FOCAD | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as COSV58096526; called by muse, mutect2
- FOXG1 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV57396092; called by muse, mutect2, varscan2
- FOXJ2 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50817989, COSV99368440; called by muse, mutect2, varscan2
- FOXJ2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50818010; called by muse, mutect2
- FOXK1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV61065272; called by muse, varscan2
- FOXN1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV56881259; called by muse, mutect2, varscan2
- FOXN1 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs768671496, COSV56880493, COSV99881557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXN1 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56881281; called by muse, mutect2, varscan2
- FPR1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs564702916, COSV59051589; called by mutect2, varscan2
- FPR3 | c.911T>C p.F304S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328946; called by muse, mutect2, varscan2
- FRAS1 | c.3899C>G p.S1300C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs1433059189, COSV53602025; called by muse, mutect2, varscan2
- FRAS1 | c.11840C>T p.P3947L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53602085; called by muse, mutect2, varscan2
- FRMD7 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53744727, COSV53745506; called by muse, mutect2, varscan2
- FRMPD3 | c.4073G>A p.R1358K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV52188836; called by muse, mutect2, varscan2
- FRMPD4 | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV66213292; called by muse, varscan2
- FRMPD4 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.923); catalogued as rs1178348008, COSV66211327; called by muse, varscan2
3,034 further variants in this file (1,539 protein-altering or splice-affecting, 1,416 silent, 79 other) are not listed here.
